National Lung Screening Trial (NLST) participant 204385 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 64 years; Gender: female; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 27 cm, reconstruction filter Siemens B50F / Siemens B30.
- T1 (day 368): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 28 cm, reconstruction filter Siemens B50F / Siemens B30.
- T2 (day 762): Negative screen, minor abnormalities not suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 40 effective mAs, display field of view 29 cm, reconstruction filter Siemens B50F / Siemens B30.

Abnormalities recorded by the reading radiologist on the CT screens (15 abnormalities and 1 comparison-read record listed separately because the form numbering for that year does not link them to an abnormality of the same type; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T0 abnormality 2: Benign lung nodule(s) (benign calcification).
- T0 abnormality 3: Emphysema.
- T0 abnormality 4: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T0 abnormality 5: Other minor abnormality noted.
- T1 abnormality 1: Other minor abnormality noted.
- T1 abnormality 2: Emphysema.
- T1 abnormality 3: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T1 abnormality 4: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T1 abnormality 5: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right lower lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 94.
- T1 comparison-read record 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); pre-existing on earlier images (earliest visible day 0); interval growth; no suspicious change in attenuation.
- T2 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 2: Emphysema.
- T2 abnormality 3: Other minor abnormality noted.
- T2 abnormality 4: Reticular/reticulonodular opacities, honeycombing, fibrosis, scar.
- T2 abnormality 5: Other minor abnormality noted.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,294.
